CCDI case PBCSEX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/7cf2d7dc-1187-4abd-8a19-3097fbed37c5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.0 years (4,002 days).

Biospecimens (3 samples)
- Sample 0DY43B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DY447: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DY44J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
